Gene-level copy-number profile of tumor specimen TCGA-61-2113-01A from TCGA case TCGA-61-2113, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 54.0 years (19,722 days).
Specimen TCGA-61-2113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3746895b-2ff1-4dcb-9001-6023ebe66a34.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2113-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/08bbd2fb-4b61-45bd-b537-25393a67969a

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 627; copy number 2: 2,366; copy number 3: 6,775; copy number 4: 11,978; copy number 5: 17,659; copy number 6: 6,527; copy number 7: 8,610; copy number 8: 3,584; copy number 9: 20; copy number 10: 188; copy number 11: 964; copy number 12: 29; copy number 13: 75; copy number 14: 115; copy number 15: 67; copy number 16: 162; copy number 17: 36; copy number 47: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2113-01A-01D-0663-01): tumor purity 0.49, ploidy 4.63, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,276 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:15,246,069–15,522,042, 1 gene, copy number 12 (within-gene range 6–12): JARID2.
- chr6:15,522,195–16,295,549, 16 genes, copy number 12: 5S_rRNA, DTNBP1, AL021978.1, ARPC3P5, LINC02543, AL365265.1, MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1.
- chr6:17,759,183–22,654,455, 52 genes, copy number 16 (within-gene range 5–16): KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1.
- chr6:66,710,242–70,303,084, 26 genes, copy number 11: AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1.
- chr8:100,475,667–145,066,685, 696 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr12:24,566,964–25,648,579, 28 genes, copy number 47: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1.
- chr15:78,293,286–80,404,214, 65 genes, copy number 15 (broad region; genes not listed).
- chr15:80,433,795–80,445,152, 2 genes, copy number 15: AC016705.1, AC016705.3.
- chr15:84,884,654–85,825,730, 32 genes, copy number 13: SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP.
- chr15:93,035,273–94,589,259, 23 genes, copy number 11–17: RGMA, YBX2P2, AC108457.1, AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2, AC009432.2, LINC02852.
- chr19:27,638,483–29,015,160, 34 genes, copy number 11: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532.
- chr19:29,775,504–34,355,566, 93 genes, copy number 12–17 (within-gene range 7–17) (broad region; genes not listed).
- chr19:38,244,035–40,094,406, 110 genes, copy number 16 (broad region; genes not listed).
- chr22:33,162,226–33,922,841, 1 gene, copy number 14 (within-gene range 8–14): LARGE1.
- chr22:33,436,582–36,267,530, 53 genes, copy number 14: MIR4764, SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1.
- chr22:36,286,847–36,286,907, 1 gene, copy number 14: MIR6819.
- chr22:39,120,167–40,682,814, 43 genes, copy number 13: CBX7, COX5BP7, AL031846.2, FUNDC2P4, PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43, SYNGR1, AL022326.2, TAB1, MGAT3, MGAT3-AS1, MIEF1, AL022312.1, ATF4, RPS19BP1, CACNA1I, ENTHD1, MTFR2P2, RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1.

Autosomal genes at a single copy (total copy number 1): 627. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
